Somatic mutation profile of tumor specimen TARGET-20-PARHUP-09A (aliquot TARGET-20-PARHUP-09A-01D) from TARGET case TARGET-20-PARHUP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.3 years (5,942 days).
Specimen TARGET-20-PARHUP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3471133d-b4fd-4380-ad5d-1d39258e148e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHUP-14A (Bone Marrow Normal), aliquot TARGET-20-PARHUP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10cead23-0fea-4af2-8706-3cb691881699

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 18/184 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ETS2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as rs762726949; called by muse, mutect2, varscan2
- WT1 | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); catalogued as CM042136, COSV60066774, COSV60069640; called by muse, mutect2, varscan2
